Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H0, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H0-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

Gender: X
Reported:
Submitting Physicians:
Pathologist:
Intraop Pathologist:
Performing Physician:

Service:

Received:

CLINICAL HISTORY:
LEFT HEPATOCELLULAR CA

PREOPERATIVE DIAGNOSIS:
HEPATOCELLULAR

SPECIMEN TYPE(S):
A: CELIAC LN, FS (1)
B: NODULE RT LOBE OF LIVER, FS (1)
C: GALLBLADDER
D: LT LOBE LIVER
E: LT HEPATIC VEIN STUMP
F: LT VEIN MARGIN, FS

FINAL DIAGNOSIS:
A. LYMPH NODE, CELIAC, BIOPSY:
Negative for malignancy.
B. LIVER, RIGHT LOBE NODULE, BIOPSY:
Negative for malignancy.
C. GALLBLADDER, RESECTION:
Chronic cholecystitis.
D. LIVER, LEFT LOBE, RESECTION:
Well differentiated hepatocellular carcinoma.
See Key Pathological Findings.
E. LEFT HEPATIC VEIN STUMP:
Negative for malignancy.
F. LEFT VEIN MARGIN:
Negative for malignancy.

KEY PATHOLOGICAL FINDINGS:

KEY PATHOLOGICAL FINDINGS

Specimen type:	partial resection
Tumor configuration:	satellite nodules
Tumor size:	8 cm in maximum dimension
Histologic type:	hepatocellular carcinoma
Histologic grade:	well-differentiated
Tumor necrosis:	Present
Extent of invasion:	Invades hepatic vein
Perineural invasion:	Absent
Parenchymal margin:	Negative
Bile duct margin:	Not assessed
Other margins:	Not applicable
Venous (large vessel) invasion:	Present
Lymph nodes:	0/1
Pathologic stage:	T3N0M1 Yes

ICD O-3
Carcinoma, hepatocellular
NDS 8170/3
Site: Liver C22.0
Jed 4/28/14

[page 2 of 3]
I, _____, the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by:

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:

FSA: CELIAC LYMPH NODE:
Lymph node with no evidence of malignancy.

FSP: NODULE RIGHT LOBE OF LIVER:
Mild portal inflammation.
No carcinoma identified.

FSP: FINAL VEIN MARGIN:
Fibrosis and chronic inflammation.
No evidence of malignancy.

_____, _____, have performed the intraoperative consultations and issued the above diagnoses.

GROSS DESCRIPTION:

- A. Specimen A is labeled "celiac lymph node, FS". Received fresh is a tan-brown lymph node measuring 2.6 x 1.6 x 0.8 cm. The specimen is bisected and half of the specimen is frozen. The frozen section residue is submitted in cassette FSA. The remaining tissue is submitted in cassette A.
- B. Specimen B is labeled "nodule right lobe of liver, FS". Received fresh are two tan-brown cylindrical fragments of soft tissue measuring from 0.8 up to 1.5 cm in length each with an average diameter of 0.1 cm. The specimen is frozen in its entirety and the frozen section residue is submitted in cassette FSB.
- C. Specimen C is labeled "gallbladder". Received fresh is an oblong gallbladder measuring 10.0 x 3.5 x 1.3 cm. The serosal surface is green-tan and unremarkable. There are multiple lymph nodes attached to the gallbladder. The cystic duct is identified and measures 1.7 cm in length. The specimen is opened to reveal a green-tan trabecular mucosa. The specimen has a wall thickness of 0.8 cm. No lesions or calculi are grossly appreciated. Representative sections are submitted as follows:
- C1: Gallbladder, back, fundus, and cystic duct margin
- C2: Four single lymph nodes
- D. Specimen D is labeled "left lobe liver". Received fresh is a left hepatectomy weighing 716.0 gm, 18.5 x 9.5 x 6.0 cm. The capsule of the liver is distorted by multiple white-tan nodules measuring from 1.5 up to 9.0 cm in greatest dimension. The hepatic vein appears to be involved by tumor. The resection margin is inked black and the specimen is serially sectioned to reveal a 7.5 X 5 X 4 cm tumor mass composed of confluent nodules with satellite nodules throughout the parenchyma. The nodules are white-tan, soft, necrotic, hemorrhagic cut surface. The nodules are located 1.4 cm from the closest inked resected margin. The uninvolved liver parenchyma is tan-brown and unremarkable. Representative sections are submitted to the Tissue Procurement Laboratory. Representative sections are submitted as follows:
- D1: Tumor in relation to the hepatic vein and artery
- D2: Tumor in relation to the inked resected margin
- D3: Section of the tumor in relation to the capsule
- D4: Uninvolved liver parenchyma
- E. Specimen E is labeled "left hepatic vein stump". Received fresh is the left

[page 3 of 3]
hepatic vein stump measuring 3.0 x 1.0 x 0.4 cm. The specimen has a single stapled margin line. The specimen is received inked on one side. The inked margin designates the true margin. The margin is reinked blue and submitted in toto in cassette B.

F. Specimen F is labeled "final vein margin-liver, FS". Received fresh is a red-brown irregular fragment of soft tissue measuring 1.5 x 0.8 x 0.3 cm. The specimen is frozen in its entirety and the frozen section residue is submitted in cassette A.

Source: NCI Genomic Data Commons file 0591689a-1581-4c8b-8d62-27841e9dffe0 (TCGA-2Y-A9H0.33EB4235-F58D-4AB6-8944-F2B59374A5F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).